Somatic mutation profile of tumor specimen TCGA-27-1838-01A (aliquot TCGA-27-1838-01A-01D-1494-08) from TCGA case TCGA-27-1838, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.4 years (21,706 days).
Specimen TCGA-27-1838-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d522d4cd-533a-4ab0-8095-b7baae2a29a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1838-10A (Blood Derived Normal), aliquot TCGA-27-1838-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33485a89-8af0-43d6-b627-264ac90b9bb9

The open-access MAF lists 98 somatic variants for this specimen: 79 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 17, Nonsense Mutation 6, Intron 2, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 2165/2332 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.821G>C p.W274S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1010008, CM151667, COSV100909695, COSV64288869; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 31/60 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 21/60 reads (35%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC9 | c.4349G>C p.S1450T | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53973822; called by muse, mutect2, varscan2
- ABCC9 | c.3936C>G p.I1312M | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1464437301, COSV53973850; called by muse, mutect2, varscan2
- ABCC9 | c.3823C>T p.Q1275* | Nonsense Mutation (SNP) | VAF 105/461 reads (23%) | catalogued as COSV53973871; called by muse, mutect2, varscan2
- ABCC9 | c.3648C>A p.N1216K | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV53973892, COSV53987514; called by muse, mutect2, varscan2
- AFAP1L2 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 134/194 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs540007841, COSV58415352; called by muse, mutect2, varscan2
- ALLC | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs750935372, COSV52994991; called by muse, mutect2, varscan2
- ANGPT4 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as COSV67921693; called by muse, mutect2, varscan2
- ANK1 | c.4339A>T p.S1447C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55883180; called by muse, mutect2, varscan2
- AQP8 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1246849945, COSV54845619; called by muse, mutect2, varscan2
- CCDC42 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 12/139 reads (9%) | catalogued as COSV53448904; called by muse, mutect2
- CDCA3 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV57528952; called by muse, mutect2
- CUL9 | c.2687C>A p.T896K | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV52729378, COSV52734483; called by muse, mutect2, varscan2
- DCTN6 | c.573A>C p.*191Yext*6 | Nonstop Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV55317812; called by muse, mutect2, varscan2
- DGKB | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51787150; called by muse, mutect2, varscan2
- DHX58 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV52426155; called by muse, mutect2, varscan2
- DNAH9 | c.2657C>A p.S886Y | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52352686, COSV52371933; called by muse, mutect2, varscan2
- DSG4 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 97/139 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186256193, COSV57392449; called by muse, mutect2, varscan2
- DUOX2 | c.4226T>G p.M1409R | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV66532515; called by muse, mutect2
- EPHA8 | c.2464T>C p.W822R | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51271234; called by muse, mutect2
- FBN3 | c.2533C>G p.P845A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV54462473; called by muse, mutect2, varscan2
- FCRL5 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62515146; called by muse, mutect2, varscan2
- FSTL5 | c.809G>C p.C270S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60198762; called by muse, mutect2, varscan2
- GABRB1 | c.500G>T p.R167I | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54980313; called by muse, mutect2, varscan2
- HEATR6 | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51746206; called by muse, mutect2, varscan2
- HPSE | c.1506G>C p.M502I | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV60987018; called by muse, mutect2, varscan2
- HTR1F | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60389862, COSV60389874; called by muse, mutect2, varscan2
- IGHV3-11 | c.213T>A p.S71R | Missense Mutation (SNP) | VAF 198/416 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.058); catalogued as rs782640314; called by muse, mutect2, varscan2
- IL1R1 | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV52106372; called by muse, mutect2, varscan2
- IL33 | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV67343178; called by muse, mutect2, varscan2
- ITPR3 | c.3353G>A p.R1118Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1256888613, COSV65405632, COSV65410202; called by muse, mutect2
- KCNJ16 | c.720A>T p.L240F | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV52253674; called by muse, mutect2
- KIAA1210 | c.4612G>A p.V1538I | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772547091, COSV68176457; called by muse, mutect2, varscan2
- LGSN | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 128/304 reads (42%) | catalogued as rs1329701342, COSV65727378; called by muse, mutect2, varscan2
- LMNTD2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756169752, COSV54241882; called by muse, mutect2, varscan2
- LRIT3 | c.1364C>A p.A455E | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59985700; called by muse, mutect2
- MAT1A | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 66/94 reads (70%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs370173781; called by muse, mutect2, varscan2
- MSH6 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 89/373 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1253844411, COSV52280100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.6391G>A p.A2131T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1281863285, COSV54234036; called by muse, mutect2, varscan2
- MYOZ2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748259386, COSV61085069; called by muse, mutect2, varscan2
- NIBAN2 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541599134, COSV64824507; called by muse, mutect2, varscan2
- NPAP1 | c.1699T>C p.S567P | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV61507612; called by muse, mutect2, varscan2
- NUP107 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs766395497, COSV57494068; called by muse, mutect2, varscan2
- NXPE3 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.022); catalogued as COSV56290135; called by muse, mutect2
- OR8H2 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV57945064; called by muse, mutect2, varscan2
- OSMR | c.1243T>A p.W415R | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57085920; called by muse, mutect2, varscan2
- PGR | c.2127C>A p.D709E | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV54802313; called by muse, mutect2, varscan2
- PTPRT | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61958806; called by muse, mutect2, varscan2
- RAD51AP2 | c.3149G>T p.W1050L | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67588206; called by muse, mutect2, varscan2
- RELN | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as COSV59005633; called by muse, mutect2, varscan2
- RENBP | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60072905; called by muse, mutect2
- RGS22 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs545074494, COSV62660807; called by muse, mutect2, varscan2
- SH3RF2 | c.968T>G p.I323S | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63039207; called by muse, mutect2, varscan2
- SIRPA | c.1241A>T p.E414V | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV61539156; called by muse, mutect2
- SIRPB1 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99498213; called by muse, mutect2
- SLC22A2 | c.1352G>T p.C451F | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65266660; called by muse, mutect2, varscan2
- SLC9A4 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs368438401; called by muse, mutect2, varscan2
- SLC9A7 | c.1711_1713del p.N571del | In Frame Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs746256363; called by pindel, varscan2
- SMARCA2 | c.210G>C p.M70I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV61808283; called by muse, mutect2, varscan2
- SPTA1 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 130/382 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372067263, COSV63749356; called by muse, mutect2, varscan2
- TAS2R16 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.065); catalogued as rs1207059482, COSV50797227; called by muse, mutect2, varscan2
- TRA2A | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51716716, COSV51717061; called by muse, mutect2, varscan2
- TRPV6 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV63892000; called by muse, mutect2, varscan2
- TSGA10 | c.1923G>A p.R641= | Splice Region (SNP) | VAF 55/126 reads (44%) | catalogued as COSV61823532; called by muse, mutect2, varscan2
- USP9X | c.5759G>C p.C1920S | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV61069698; called by muse, mutect2
- XIRP2 | c.5116C>T p.R1706* (on ENST00000628543; = p.R1881* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 59/159 reads (37%) | catalogued as rs374157391; called by muse, mutect2, varscan2
- ZNF17 | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56921555; called by muse, mutect2, varscan2
- ZNF263 | c.1188C>A p.H396Q | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV54596671; called by muse, mutect2, varscan2
- ZNF462 | c.1369C>G p.H457D | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as COSV52939920; called by muse, mutect2, varscan2
- ZNF484 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 127/425 reads (30%) | catalogued as COSV60257678, COSV60257947; called by muse, mutect2, varscan2
- ZNF655 | c.1199G>T p.R400I | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1313642846, COSV53158887, COSV53159927; called by muse, mutect2, varscan2
- ZP1 | c.529C>G p.H177D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV53924727; called by muse, mutect2, varscan2
- KCNK16 | c.894_910del p.D299Efs*23 | Frame Shift Del (DEL) | VAF 17/213 reads (8%) | called by mutect2, pindel
- OR5D16 | c.723_727dup p.C243Sfs*7 | Frame Shift Ins (INS) | VAF 48/213 reads (23%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2789A>G p.H930R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ABCC10 | c.3216G>A p.P1072= (on ENST00000372530 / NM_001198934.2; = p.P1044= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as rs1186587542, COSV55088641, COSV55091003; called by muse, mutect2, varscan2
- AMIGO3 | c.114T>C p.C38= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as rs185704507; called by muse, mutect2, varscan2
- CDH19 | c.705G>A p.A235= | Silent (SNP) | VAF 84/113 reads (74%) | catalogued as rs367564105; called by muse, mutect2, varscan2
- DCAF12L1 | c.288G>A p.T96= | Silent (SNP) | VAF 47/182 reads (26%) | catalogued as rs755461394, COSV64421925; called by muse, mutect2, varscan2
- FBLN5 | c.1092C>T p.D364= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV50904238; called by muse, mutect2
- GCM1 | c.735A>G p.G245= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV52522153; called by muse, mutect2, varscan2
- GDF10 | c.498G>A p.P166= | Silent (SNP) | VAF 14/17 reads (82%) | called by muse, mutect2, varscan2
- GHRHR | c.300C>A p.G100= | Silent (SNP) | VAF 58/414 reads (14%) | catalogued as COSV58196710; called by muse, mutect2, varscan2
- OR2AK2 | c.894G>A p.T298= | Silent (SNP) | VAF 62/161 reads (39%) | catalogued as rs1264373316, COSV100824168, COSV63553745, COSV63556785; called by muse, mutect2, varscan2
- OR4A15 | c.300T>C p.F100= | Silent (SNP) | VAF 58/722 reads (8%) | catalogued as COSV100124103, COSV59035550; called by muse, mutect2
- PAPOLA | c.297A>G p.T99= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV53481892; called by muse, mutect2, varscan2
- PCDHA12 | c.201G>A p.A67= | Silent (SNP) | VAF 87/245 reads (36%) | catalogued as COSV56475835; called by muse, mutect2, varscan2
- PCLO | c.14013C>T p.P4671= | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as COSV61639005; called by muse, mutect2, varscan2
- PHF3 | c.4683A>G p.R1561= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV50320765; called by muse, mutect2, varscan2
- PLEKHA2 | c.909C>T p.H303= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs778803047, COSV66242782; called by muse, mutect2, varscan2
- SSX7 | c.453T>C p.I151= | Silent (SNP) | VAF 28/468 reads (6%) | catalogued as COSV53340110; called by muse, mutect2
- TRIM71 | c.2043G>A p.T681= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as rs761536522, COSV67470096; called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2765G>A | Intron (SNP) | VAF 54/225 reads (24%) | catalogued as rs777529292, COSV99805636; called by muse, mutect2, varscan2
- MYB | c.1203+970A>T | Intron (SNP) | VAF 73/259 reads (28%) | catalogued as COSV100214647; called by muse, mutect2, varscan2
